Somatic mutation profile of tumor specimen C3N-05114-01 (aliquot CPT0375840007) from CPTAC case C3N-05114, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.5 years (24,283 days).
Specimen C3N-05114-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36e4fb01-0365-419f-b999-eba2082ec046.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05114-31 (Blood Derived Normal), aliquot CPT0375900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90226de1-fb96-4d53-8a50-5e49c1fcdbde

The open-access MAF lists 79 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 15, Intron 5, RNA 4, Frame Shift Del 2, Splice Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 3444/4593 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by muse, mutect2, varscan2
- PTEN | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs864622341, COSV64290156; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2
- AFAP1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); catalogued as rs374198857; called by muse, mutect2, varscan2
- APLNR | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs750760773, COSV57242589; called by muse, mutect2, varscan2
- ART1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs537517512, COSV99167151, COSV99167212; called by muse, mutect2, varscan2
- BARHL2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1230062780; called by muse, varscan2
- BORCS8-MEF2B | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as rs766141253, COSV50767126; called by muse, mutect2, varscan2
- C10orf71 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368058122, COSV100110672; called by muse, mutect2, varscan2
- CPNE4 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs768298078; called by muse, mutect2, varscan2
- CRB1 | c.2366A>G p.N789S | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV66333324; called by muse, mutect2, varscan2
- CSNK1A1 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as rs751956468; called by muse, mutect2, varscan2
- CSRNP3 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as COSV58777634; called by muse, mutect2, varscan2
- EPHA7 | c.1482A>T p.K494N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV65180387; called by muse, mutect2, varscan2
- FCRL2 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749857247, COSV63833440; called by muse, mutect2, varscan2
- KRT36 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 91/447 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs775869901, COSV100057288; called by muse, mutect2, varscan2
- LCE6A | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs766698961, COSV70391417; called by muse, mutect2, varscan2
- LILRB1 | c.2024G>A p.R675Q (on ENST00000427581; = p.R624Q on NM_006669.6) | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as rs753349590, COSV61116699; called by muse, mutect2, varscan2
- MET | c.2225C>A p.P742H | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59257169; called by muse, mutect2
- MRGPRX2 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.104); catalogued as rs200815634, COSV61674398; called by muse, mutect2, varscan2
- NGF | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as rs201087374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGA8 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.014); catalogued as rs1034199960, COSV53906907; called by muse, mutect2, varscan2
- PKHD1 | c.5185G>A p.A1729T | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61895863; called by muse, mutect2, varscan2
- RP1L1 | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1008642662; called by muse, mutect2, varscan2
- SERPINA9 | c.833A>G p.K278R | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs747482522; called by muse, mutect2, varscan2
- SIM1 | c.1800A>C p.K600N | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.378); catalogued as COSV99492165; called by muse, mutect2, varscan2
- STAT6 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.341); catalogued as rs1349855395; called by muse, mutect2, varscan2
- SYNE3 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs1202376572; called by muse, mutect2, varscan2
- TAF1A | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV61919629; called by muse, mutect2, varscan2
- TMC7 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs779355742, COSV58583008; called by muse, mutect2, varscan2
- TPO | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs751244187, COSV61108938; called by muse, mutect2, varscan2
- ADAM7 | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AUP1 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by mutect2, varscan2
- COL5A1 | c.5392A>G p.T1798A | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- CORIN | c.524del p.F175Sfs*56 | Frame Shift Del (DEL) | VAF 38/325 reads (12%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.257A>C p.Y86S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FAM83B | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- FLACC1 | c.882G>C p.E294D | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FNDC3B | c.910T>C p.C304R | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FRY | c.3670A>T p.I1224F | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- FZD9 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HTRA3 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ILF3 | c.89C>G p.A30G | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LIMD1 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- LRTM2 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- MMRN1 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPIPB6 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 47/515 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OSBPL10 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2
- PPP1R37 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RPL11 | c.262-1G>T p.X88_splice (on ENST00000374550 / NM_001199802.1; = p.X89_splice on NM_000975.5) | Splice Site (SNP) | VAF 23/282 reads (8%) | called by muse, mutect2
- SF3B3 | c.3506del p.P1169Lfs*2 | Frame Shift Del (DEL) | VAF 36/184 reads (20%) | called by mutect2, pindel, varscan2
- SYNE1 | c.8098C>G p.Q2700E (on ENST00000367255 / NM_182961.4; = p.Q2707E on NM_033071.3) | Missense Mutation (SNP) | VAF 71/313 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- UBTF | c.2214_2216del p.D738del | In Frame Del (DEL) | VAF 35/192 reads (18%) | called by mutect2, pindel, varscan2
- ZDHHC7 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ZNF839 | c.461A>G p.E154G (on ENST00000558850 / NM_001267827.1; = p.E270G on NM_018335.5) | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ATP8B3 | c.1347C>T p.S449= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs186172399, COSV59546689; called by muse, mutect2, varscan2
- C3 | c.561C>T p.G187= | Silent (SNP) | VAF 108/422 reads (26%) | catalogued as rs750854072; called by muse, mutect2, varscan2
- DNAH5 | c.12993C>T p.D4331= | Silent (SNP) | VAF 102/506 reads (20%) | catalogued as rs750130912; called by muse, mutect2, varscan2
- EPHA6 | c.825G>A p.R275= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- FREM2 | c.3480G>A p.E1160= | Silent (SNP) | VAF 21/252 reads (8%) | called by muse, mutect2
- GLP2R | c.1350C>T p.Y450= | Silent (SNP) | VAF 21/97 reads (22%) | called by mutect2, varscan2
- GUCY2D | c.1524C>T p.D508= | Silent (SNP) | VAF 41/191 reads (21%) | catalogued as rs200651999, COSV99643859; called by muse, mutect2, varscan2
- ITLN1 | c.231C>T p.G77= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs142720493; called by muse, mutect2
- MROH2A | c.3396G>A p.P1132= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs559079967; called by muse, mutect2, varscan2
- NYX | c.492C>A p.L164= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as rs1490946818; called by muse, mutect2, varscan2
- OXGR1 | c.930G>A p.Q310= | Silent (SNP) | VAF 41/185 reads (22%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1632C>T p.S544= | Silent (SNP) | VAF 168/2358 reads (7%) | catalogued as COSV50808562; called by muse, mutect2
- SLC52A2 | c.246G>A p.R82= | Silent (SNP) | VAF 88/359 reads (25%) | catalogued as rs1554853885; called by muse, mutect2, varscan2
- TESC | c.372G>A p.S124= | Silent (SNP) | VAF 39/241 reads (16%) | catalogued as rs781608300; called by muse, mutect2, varscan2
- TRHDE | c.18C>T p.A6= | Silent (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- AC244394.2 | n.1281G>A | RNA (SNP) | VAF 41/288 reads (14%) | catalogued as rs782148513; called by muse, mutect2, varscan2
- KSR2 | c.*21G>A | 3'UTR (SNP) | VAF 4/23 reads (17%) | catalogued as rs767356805, COSV100194694; called by muse, mutect2, varscan2
- LDLR | c.67+1205C>T | Intron (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2
- LINC00470 | n.1367A>T | RNA (SNP) | VAF 37/112 reads (33%) | called by muse, mutect2, varscan2
- MGRN1 | c.795+982T>C | Intron (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- ODF2 | c.420+9G>A | Intron (SNP) | VAF 41/205 reads (20%) | called by muse, mutect2, varscan2
- PACS2 | c.1614-31C>T | Intron (SNP) | VAF 34/152 reads (22%) | catalogued as rs1419743243; called by muse, mutect2, varscan2
- REXO1L1P | n.745C>T | RNA (SNP) | VAF 44/1504 reads (3%) | called by muse, mutect2
- THOC5 | c.967-118A>G | Intron (SNP) | VAF 46/180 reads (26%) | called by muse, mutect2, varscan2
- TUBB7P | n.48C>T | RNA (SNP) | VAF 46/328 reads (14%) | catalogued as rs782452013; called by muse, mutect2, varscan2
